Somatic mutation profile of tumor specimen CDDP-ACQ7-TTP1-A (aliquot CDDP-ACQ7-TTP1-A-1-0-D-A572-36) from CDDP_EAGLE case CDDP-ACQ7, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 55 years.
Specimen CDDP-ACQ7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d70d7169-db51-418a-af51-376252d3faa9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACQ7-NB1-A (Blood Derived Normal), aliquot CDDP-ACQ7-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7b9a2b5-db53-4fa8-9c43-8a803ccf3e8d

The open-access MAF lists 314 somatic variants for this specimen: 210 protein-altering or splice-affecting, 54 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 171, Silent 54, Intron 24, Nonsense Mutation 17, Frame Shift Del 10, RNA 8, 5'UTR 7, Splice Site 6, 5'Flank 6, 3'UTR 5, Frame Shift Ins 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 72/201 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.532del p.H178Tfs*69 | Frame Shift Del (DEL) | VAF 49/108 reads (45%) | catalogued as rs786202525, CD983489, CM111332, COSV52693338, COSV52783253, COSV52816064; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ABCA6 | c.3665G>T p.G1222V | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs149663995; called by muse, mutect2, varscan2
- ABCC10 | c.275G>T p.G92V (on ENST00000372530 / NM_001198934.2; = p.G49V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99768279; called by muse, mutect2, varscan2
- ABCC8 | c.2051G>T p.G684V | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as CM107389, COSV56849193; called by muse, mutect2, varscan2
- ADAMTS14 | c.2954G>T p.G985V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64600763; called by muse, mutect2, varscan2
- ADGRV1 | c.5401G>T p.E1801* | Nonsense Mutation (SNP) | VAF 36/145 reads (25%) | catalogued as COSV67989879; called by muse, mutect2, varscan2
- AKAP9 | c.2752G>A p.D918N | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.101); catalogued as COSV62356937; called by muse, mutect2, varscan2
- ANK2 | c.8992del p.Q2998Nfs*33 | Frame Shift Del (DEL) | VAF 49/239 reads (21%) | catalogued as COSV99999876; called by mutect2, pindel, varscan2
- ARHGEF19 | c.1090A>G p.S364G | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99580848; called by muse, mutect2, varscan2
- BEGAIN | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100766993, COSV62068543; called by muse, mutect2
- C2orf78 | c.2564G>T p.R855L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs200514281; called by muse, mutect2
- CASP12 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs892377468; called by muse, varscan2
- CATSPER1 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.334); catalogued as COSV56410388; called by muse, mutect2, varscan2
- CD1E | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV63771105; called by muse, mutect2, varscan2
- CNBD1 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs1214418811; called by muse, mutect2, varscan2
- CNTN5 | c.2673G>T p.E891D | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV99672377, COSV99674766; called by muse, mutect2, varscan2
- COL4A1 | c.2948C>A p.A983E | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.898); catalogued as rs956773650; called by muse, mutect2, varscan2
- COPB1 | c.862T>G p.L288V | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV51450672; called by muse, mutect2, varscan2
- DGKB | c.2295G>T p.Q765H | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51780909; called by muse, mutect2, varscan2
- DLGAP2 | c.874G>T p.G292C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV70102657; called by muse, mutect2, varscan2
- DLGAP3 | c.2339G>C p.R780P | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.925); catalogued as rs745644846; called by muse, mutect2, varscan2
- DRC7 | c.1240C>A p.P414T | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1351855550; called by muse, mutect2, varscan2
- EPSTI1 | c.938G>A p.G313D (on ENST00000398762 / NM_001330543.2; = p.G302D on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as rs1205700186; called by muse, mutect2, varscan2
- EVPL | c.3973G>A p.V1325M | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as rs574918697, COSV100043777; called by muse, mutect2, varscan2
- FAT3 | c.1390G>C p.D464H | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53077033, COSV53187344; called by muse, mutect2, varscan2
- FGD2 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs746649633, COSV51463206; called by muse, mutect2, varscan2
- FSIP2 | c.14101G>T p.V4701L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as rs1451942972; called by muse, mutect2, varscan2
- GAS2 | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441322956; called by muse, mutect2
- GRK7 | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as COSV99379713; called by muse, mutect2, varscan2
- H4C3 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); catalogued as rs1297061490; called by muse, mutect2, varscan2
- HTR4 | c.901G>T p.G301C | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58792288; called by muse, mutect2, varscan2
- IGSF10 | c.2201A>G p.H734R | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs370689880; called by muse, mutect2, varscan2
- KDM3B | c.350G>T p.W117L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58692759; called by muse, mutect2, varscan2
- KRT27 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs760091102; called by muse, mutect2, varscan2
- KRTAP9-9 | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs776793449; called by muse, mutect2, varscan2
- LMAN1 | c.1480G>T p.G494C | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV99195357; called by muse, mutect2, varscan2
- MACROD2 | c.1267G>T p.G423W (on ENST00000642719; = p.G395W on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV99426899; called by muse, mutect2, varscan2
- MED30 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52067733; called by muse, mutect2, varscan2
- MUC5B | c.4222G>A p.A1408T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.357); catalogued as rs373767452; called by muse, mutect2, varscan2
- NCR1 | c.70+1G>A p.X24_splice | Splice Site (SNP) | VAF 47/170 reads (28%) | catalogued as rs1452973956; called by muse, mutect2, varscan2
- NUP93 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57430679; called by mutect2, varscan2
- OBSCN | c.15907G>T p.A5303S | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs376588743; called by muse, mutect2, varscan2
- OR13C9 | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs745687355; called by muse, mutect2, varscan2
- OR4A15 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as COSV59034185; called by muse, mutect2, varscan2
- PAPOLB | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1219701263; called by muse, mutect2, varscan2
- PCDH15 | c.4781G>T p.S1594I (on ENST00000644397 / NM_001354429.2; = p.S1536I on NM_001142771.2) | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); catalogued as rs766639357; called by muse, mutect2, varscan2
- PGAP4 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1015973436; called by muse, mutect2, varscan2
- PKHD1 | c.2746C>A p.H916N | Missense Mutation (SNP) | VAF 154/310 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100581184; called by muse, mutect2, varscan2
- PSMC3 | c.802G>T p.V268F | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54082248; called by muse, mutect2, varscan2
- PTPRC | c.3645+1G>T p.X1215_splice | Splice Site (SNP) | VAF 100/326 reads (31%) | catalogued as COSV61411675; called by muse, mutect2, varscan2
- PYCR3 | c.607A>T p.S203C | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.547); catalogued as rs1254088177; called by muse, mutect2, varscan2
- RIT2 | c.499A>G p.R167G | Missense Mutation (SNP) | VAF 80/260 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs758760009, COSV100451040; called by muse, mutect2, varscan2
- RIT2 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 64/233 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs754435765, COSV56308980; called by muse, mutect2, varscan2
- RNGTT | c.1550G>C p.C517S | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55645521; called by muse, mutect2, varscan2
- RPEL1 | c.263C>G p.A88G | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.997); catalogued as COSV101483132; called by muse, mutect2, varscan2
- RYR2 | c.6261G>T p.L2087F | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63674287; called by muse, mutect2, varscan2
- SPTA1 | c.6272C>T p.S2091F | Missense Mutation (SNP) | VAF 16/257 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934746; called by muse, mutect2
- STPG2 | c.222+1G>T p.X74_splice | Splice Site (SNP) | VAF 28/66 reads (42%) | catalogued as rs754945465; called by muse, varscan2
- SWAP70 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 28/155 reads (18%) | catalogued as COSV59662263; called by muse, mutect2, varscan2
- SYN1 | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 56/67 reads (84%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs1207640513, COSV104406215; called by muse, mutect2, varscan2
- TENM3 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.982); catalogued as COSV101304956, COSV69315310; called by muse, mutect2, varscan2
- TMEM132C | c.2665C>T p.P889S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV59436812; called by muse, mutect2, varscan2
- TOX2 | c.1022C>A p.S341* (on ENST00000358131 / NM_001098798.2; = p.S317* on NM_032883.3) | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV57890406; called by muse, mutect2, varscan2
- TRIML2 | c.190-1G>A p.X64_splice | Splice Site (SNP) | VAF 32/119 reads (27%) | catalogued as COSV100456047; called by muse, mutect2, varscan2
- VHLL | c.115A>G p.R39G | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60554068; called by muse, mutect2, varscan2
- VNN1 | c.1360del p.V454Cfs*10 | Frame Shift Del (DEL) | VAF 43/149 reads (29%) | catalogued as COSV100907717; called by mutect2, pindel, varscan2
- ZNF536 | c.1050C>A p.C350* | Nonsense Mutation (SNP) | VAF 28/115 reads (24%) | catalogued as COSV62831155; called by muse, mutect2, varscan2
- ZNF648 | c.1097G>T p.C366F | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs201962929; called by muse, mutect2, varscan2
- ABCA1 | c.3062T>G p.L1021W | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA12 | c.3892T>A p.F1298I (on ENST00000272895 / NM_173076.3; = p.F980I on NM_015657.3) | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ABCC11 | c.2999C>T p.S1000F | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACSBG1 | c.1114C>A p.H372N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ADAMTS12 | c.3067C>A p.P1023T | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ADAMTS16 | c.1495A>C p.K499Q | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADO | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ALDH1L1 | c.1077G>T p.R359S | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APBB1 | c.454A>T p.K152* | Nonsense Mutation (SNP) | VAF 39/109 reads (36%) | called by muse, mutect2, varscan2
- ARHGAP39 | c.2014G>T p.G672C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by mutect2, varscan2
- ATM | c.7030T>C p.W2344R | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- B3GAT1 | c.261C>A p.H87Q | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- BCL11A | c.1928G>T p.G643V (on ENST00000335712 / NM_001365609.1; = p.G677V on NM_018014.4) | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BNIP3L | c.295C>A p.Q99K | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- BTNL3 | c.953T>C p.V318A | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- BTRC | c.1408G>T p.A470S (on ENST00000370187 / NM_033637.4; = p.A434S on NM_003939.5) | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CCDC186 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 26/131 reads (20%) | called by muse, mutect2, varscan2
- CCDC186 | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC27 | c.1832T>C p.I611T | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2
- CD163 | c.3003T>G p.N1001K | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.742); called by mutect2, varscan2
- CDH13 | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH18 | c.1457C>A p.P486H | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CDH18 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2
- CDK18 | c.622G>C p.E208Q (on ENST00000506784 / NM_212503.3; = p.E178Q on NM_002596.4) | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFAP47 | c.2666C>T p.P889L | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- CHD3 | c.2630G>T p.W877L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNMD | c.219C>A p.Y73* | Nonsense Mutation (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- COL5A2 | c.4270del p.V1424Ffs*8 | Frame Shift Del (DEL) | VAF 65/290 reads (22%) | called by mutect2, pindel, varscan2
- CRIM1 | c.2380T>A p.C794S | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSMD3 | c.2946C>A p.Y982* (on ENST00000297405 / NM_001363185.1; = p.Y878* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 30/162 reads (19%) | called by muse, varscan2
- CTNNA2 | c.2006G>C p.R669P | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- CYLC1 | c.1017C>A p.D339E | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- DDC | c.315+6G>T | Splice Region (SNP) | VAF 37/142 reads (26%) | called by muse, mutect2, varscan2
- DMXL1 | c.4038G>T p.L1346F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH3 | c.10685C>A p.A3562D | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNAH8 | c.12073G>T p.G4025C | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNMT3A | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPRX | c.101T>C p.L34S | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- EIF4G3 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- ELK1 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ERICH3 | c.3490_3491insT p.E1164Vfs*21 | Frame Shift Ins (INS) | VAF 33/72 reads (46%) | called by mutect2, pindel*, varscan2
- FAM117B | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FAT4 | c.12397G>T p.V4133F | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- FER1L5 | c.2803C>A p.R935S (on ENST00000623019; = p.R942S on NM_001293083.2) | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FNDC1 | c.3459G>T p.R1153S | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FNDC8 | c.446C>G p.A149G | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- FSHR | c.304A>T p.I102F | Missense Mutation (SNP) | VAF 70/258 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNTL6 | c.917del p.P306Lfs*29 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- GBE1 | c.416G>C p.G139A | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.081); called by muse, mutect2
- GJC1 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HHLA1 | c.1439G>T p.S480I | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HIVEP1 | c.3967G>T p.D1323Y | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN1 | c.4567T>A p.Y1523N | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HRH2 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL2RB | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | called by muse, varscan2
- KCNB2 | c.309C>A p.Y103* | Nonsense Mutation (SNP) | VAF 54/156 reads (35%) | called by muse, mutect2, varscan2
- KRT27 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KRT6C | c.1661C>A p.T554N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KRTAP13-1 | c.418C>A p.L140M | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- LRFN4 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- LRIT1 | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- LRP1B | c.7285C>A p.L2429M | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC14B | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.025); called by mutect2, varscan2
- LY75 | c.3761G>T p.C1254F | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- MANSC1 | c.870dup p.A291Cfs*47 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- MAP1A | c.290T>A p.L97* | Nonsense Mutation (SNP) | VAF 60/188 reads (32%) | called by muse, mutect2, varscan2
- MFSD9 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MICAL3 | c.2344A>T p.K782* | Nonsense Mutation (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- MRPL21 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTCL1 | c.5213A>T p.Y1738F (on ENST00000306329 / NM_001378206.1; = p.Y1419F on NM_015210.4) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NANS | c.708A>C p.E236D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV2 | c.5230C>T p.Q1744* (on ENST00000396087 / NM_001244963.2; = p.Q1688* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- NBEA | c.3323del p.Q1108Rfs*22 | Frame Shift Del (DEL) | VAF 33/155 reads (21%) | called by mutect2, pindel, varscan2
- NCL | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NEB | c.3745G>T p.A1249S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NEB | c.3744G>T p.Q1248H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NEK10 | c.1244A>G p.Y415C | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLN | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, varscan2
- NLRC5 | c.146A>T p.D49V | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- NOLC1 | c.1922A>T p.D641V | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPR3 | c.1514G>T p.R505M (on ENST00000265074 / NM_001364458.2; = p.R504M on NM_000908.4) | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR14K1 | c.728T>A p.L243H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2AJ1 | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- OR7A17 | c.594del p.M199Cfs*23 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | called by pindel, varscan2
- ORAI1 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OS9 | c.963G>T p.Q321H | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OSBPL7 | c.561G>T p.W187C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PAK3 | c.1356A>C p.K452N (on ENST00000262836 / NM_001324328.2; = p.K437N on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDH11X | c.1799G>T p.G600V | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PCDHA3 | c.668C>A p.T223N | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- PCDHB9 | c.1522G>T p.A508S | Missense Mutation (SNP) | VAF 84/277 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- PCDHGB1 | c.969C>A p.H323Q | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); called by muse, mutect2
- PDE2A | c.990G>T p.M330I | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PDS5A | c.3057A>T p.Q1019H | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PEG3 | c.2873G>T p.G958V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PLEKHG4 | c.1081G>C p.V361L | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEF | c.1166G>T p.R389M | Missense Mutation (SNP) | VAF 62/314 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- POU5F1B | c.821G>C p.R274P | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PPP1R16B | c.1474C>A p.L492M | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PROX2 | c.315G>T p.K105N | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRR35 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PTPN14 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 38/129 reads (29%) | called by muse, mutect2, varscan2
- PTPN5 | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRO | c.2304+2T>A p.X768_splice | Splice Site (SNP) | VAF 63/184 reads (34%) | called by muse, mutect2, varscan2
- RELN | c.129C>A p.H43Q | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RGS18 | c.188C>A p.S63Y | Missense Mutation (SNP) | VAF 67/251 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RP1 | c.3756G>T p.L1252F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- RYR2 | c.5353del p.D1785Tfs*11 | Frame Shift Del (DEL) | VAF 33/171 reads (19%) | called by mutect2, pindel*, varscan2
- SCART1 | c.2734C>T p.L912F | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SEC31A | c.3611T>C p.F1204S (on ENST00000355196 / NM_001318120.1; = p.F1165S on NM_016211.4) | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SGCD | c.44G>T p.G15V (on ENST00000435422 / NM_001128209.2; = p.G16V on NM_000337.5) | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SHOC2 | c.1003A>G p.S335G | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, varscan2
- SKP2 | c.414G>C p.Q138H | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLC15A5 | c.239C>A p.A80D | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC25A12 | c.1304G>T p.C435F | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SLC2A4 | c.56G>C p.R19P | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.104); called by muse, varscan2
- SLC34A2 | c.1048+2_1048+7del p.X350_splice | Splice Site (DEL) | VAF 46/236 reads (19%) | called by mutect2, pindel, varscan2
- SPG7 | c.1263G>T p.E421D (on ENST00000268704; = p.E428D on NM_003119.4) | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STK11 | c.148_149del p.L50Dfs*112 | Frame Shift Del (DEL) | VAF 31/81 reads (38%) | called by mutect2, pindel, varscan2
- SYNE1 | c.22171G>T p.E7391* (on ENST00000367255 / NM_182961.4; = p.E7320* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 51/127 reads (40%) | called by muse, mutect2, varscan2
- TEX14 | c.3312C>A p.T1104= (on ENST00000240361 / NM_001201457.2; = p.T1058= on NM_031272.5) | Splice Region (SNP) | VAF 22/107 reads (21%) | called by muse, mutect2, varscan2
- TEX14 | c.3311C>A p.T1104N (on ENST00000240361 / NM_001201457.2; = p.T1058N on NM_031272.5) | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- TIMD4 | c.787A>T p.T263S | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- TMCC3 | c.207C>G p.D69E | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- TMED3 | c.496_497insT p.G166Vfs*50 | Frame Shift Ins (INS) | VAF 24/102 reads (24%) | called by mutect2, pindel, varscan2
- TMEM117 | c.567A>T p.R189S | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TNFRSF10D | c.857A>T p.Q286L | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- TOR2A | c.641_642del p.R214Qfs*72 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | called by pindel, varscan2
- TRIM71 | c.2309G>T p.R770L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRPA1 | c.873G>T p.M291I | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- TTN | c.22087A>G p.I7363V (on ENST00000591111; = p.I6436V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | PolyPhen benign (0.078); called by muse, mutect2, varscan2
- UNC79 | c.5332A>T p.M1778L (on ENST00000393151 / NM_001346218.2; = p.M1601L on NM_020818.5) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP49 | c.1621A>G p.M541V | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- VPS13B | c.1828A>G p.S610G | Missense Mutation (SNP) | VAF 87/387 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- VSTM2B | c.425C>A p.A142D | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDFY4 | c.3604C>A p.P1202T | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.058); called by muse, mutect2
- WDR97 | c.701_703del p.L234del | In Frame Del (DEL) | VAF 46/134 reads (34%) | called by pindel, varscan2
- ZNF221 | c.1691G>T p.C564F | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ZNF260 | c.1172G>A p.S391N | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF284 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZRANB3 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADGRV1 | c.5400G>T p.L1800= | Silent (SNP) | VAF 37/144 reads (26%) | catalogued as COSV67988142; called by muse, mutect2, varscan2
- ALDH4A1 | c.498C>T p.L166= | Silent (SNP) | VAF 40/126 reads (32%) | called by muse, mutect2, varscan2
- ARAF | c.1125G>A p.R375= | Silent (SNP) | VAF 30/50 reads (60%) | called by muse, mutect2, varscan2
- ASXL3 | c.2655C>A p.V885= | Silent (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- ATXN2L | c.1272G>T p.S424= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as COSV57367634; called by muse, mutect2, varscan2
- BSN | c.3535C>A p.R1179= | Silent (SNP) | VAF 42/97 reads (43%) | called by muse, mutect2, varscan2
- C22orf42 | c.342C>A p.G114= | Silent (SNP) | VAF 36/177 reads (20%) | called by muse, mutect2, varscan2
- C2orf78 | c.2562C>A p.P854= | Silent (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2
- CACNA1E | c.1723C>A p.R575= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as COSV62393291; called by muse, mutect2, varscan2
- CNOT2 | c.1056G>T p.T352= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV57502949, COSV99972767; called by muse, mutect2, varscan2
- COL3A1 | c.3687C>A p.I1229= | Silent (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- CTNNA2 | c.718C>A p.R240= | Silent (SNP) | VAF 75/289 reads (26%) | catalogued as rs900008840; called by muse, mutect2, varscan2
- DCAF4L2 | c.337C>A p.R113= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV60478605; called by muse, mutect2, varscan2
- EID1 | c.369A>G p.R123= | Silent (SNP) | VAF 33/108 reads (31%) | called by muse, mutect2, varscan2
- ELK1 | c.87G>T p.R29= | Silent (SNP) | VAF 44/75 reads (59%) | called by muse, mutect2, varscan2
- FLRT2 | c.99C>A p.L33= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as COSV58150120; called by muse, mutect2, varscan2
- FNDC8 | c.138T>C p.T46= | Silent (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- GLDN | c.1335G>T p.S445= | Silent (SNP) | VAF 47/133 reads (35%) | called by muse, mutect2, varscan2
- HDAC3 | c.1152C>T p.L384= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as rs374647135; called by muse, mutect2, varscan2
- HEPHL1 | c.2148C>A p.V716= | Silent (SNP) | VAF 50/181 reads (28%) | catalogued as COSV100243996; called by muse, mutect2, varscan2
- HSPBP1 | c.609G>T p.T203= | Silent (SNP) | VAF 38/91 reads (42%) | called by muse, mutect2, varscan2
- IFNA10 | c.279A>G p.T93= | Silent (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- IL21R | c.411C>A p.S137= | Silent (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- ITIH5 | c.2199C>A p.G733= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- KCND2 | c.1092C>A p.T364= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs573823442; called by muse, mutect2, varscan2
- LCE3D | c.87T>C p.C29= | Silent (SNP) | VAF 57/189 reads (30%) | called by muse, mutect2, varscan2
- LETM1 | c.420G>T p.V140= | Silent (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- MUC5B | c.10218C>A p.P3406= | Silent (SNP) | VAF 130/382 reads (34%) | catalogued as rs1440686245; called by muse, varscan2
- NUTM1 | c.1242C>A p.I414= | Silent (SNP) | VAF 60/241 reads (25%) | catalogued as COSV59217525; called by muse, mutect2, varscan2
- OPALIN | c.27G>T p.L9= | Silent (SNP) | VAF 48/143 reads (34%) | called by muse, mutect2, varscan2
- OR6M1 | c.36A>C p.L12= | Silent (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- PCDHB14 | c.90T>G p.S30= | Silent (SNP) | VAF 42/135 reads (31%) | called by muse, mutect2, varscan2
- PCDHB6 | c.1965G>T p.T655= | Silent (SNP) | VAF 48/171 reads (28%) | catalogued as rs782188858, COSV50712725, COSV99170208; called by muse, mutect2, varscan2
- PCDHGA9 | c.1854G>C p.S618= | Silent (SNP) | VAF 33/156 reads (21%) | catalogued as rs774487660; called by muse, mutect2, varscan2
- PEX11B | c.589C>T p.L197= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs782628656, COSV65196663; called by muse, mutect2, varscan2
- PHLPP2 | c.1341G>T p.R447= | Silent (SNP) | VAF 39/253 reads (15%) | called by muse, mutect2, varscan2
- PKD1 | c.4081C>T p.L1361= | Silent (SNP) | VAF 66/248 reads (27%) | called by muse, mutect2, varscan2
- PRIMA1 | c.387C>T p.G129= | Silent (SNP) | VAF 39/121 reads (32%) | called by muse, mutect2, varscan2
- PRKDC | c.1566C>A p.P522= | Silent (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- PRMT3 | c.1296G>A p.L432= | Silent (SNP) | VAF 48/194 reads (25%) | called by muse, mutect2, varscan2
- PTPRD | c.2103C>A p.S701= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs756214335; called by muse, varscan2
- RAD51D | c.789C>T p.A263= | Silent (SNP) | VAF 67/226 reads (30%) | catalogued as rs1555567153; ClinVar: likely benign; called by muse, mutect2, varscan2
- RANBP2 | c.7617A>T p.S2539= | Silent (SNP) | VAF 100/497 reads (20%) | catalogued as rs143675099; ClinVar: likely benign; called by muse, mutect2
- RBM23 | c.795C>T p.L265= (on ENST00000359890 / NM_001077351.2; = p.L249= on NM_018107.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/164 reads (21%) | called by muse, mutect2, varscan2
- RIMS1 | c.940C>A p.R314= | Silent (SNP) | VAF 35/73 reads (48%) | called by muse, mutect2, varscan2
- RIMS2 | c.972G>A p.R324= (on ENST00000666250 / NM_001348490.2; = p.R132= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 110/205 reads (54%) | catalogued as COSV99031412; called by muse, mutect2, varscan2
- RUNX1T1 | c.1596C>A p.A532= (on ENST00000265814 / NM_001198628.1; = p.A505= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as COSV99751188; called by muse, mutect2, varscan2
- SLC13A3 | c.1638G>T p.R546= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- SLC13A4 | c.1410T>A p.V470= | Silent (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- TPPP2 | c.462C>A p.G154= | Silent (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- USP16 | c.1089A>T p.L363= | Silent (SNP) | VAF 35/100 reads (35%) | called by muse, mutect2, varscan2
- ZAN | c.6639C>T p.A2213= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs1262402833; called by muse, mutect2, varscan2
- ZFHX4 | c.2448G>T p.A816= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV50648020; called by muse, mutect2, varscan2
- ZRANB3 | c.408C>A p.T136= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV51498907; called by muse, mutect2, varscan2
- AC114490.3 | c.*487C>T | 3'UTR (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- AK7 | c.2134-276T>C | Intron (SNP) | VAF 6/48 reads (13%) | catalogued as rs1334656460; called by mutect2, varscan2
- AKT2 | c.288-16G>C | Intron (SNP) | VAF 23/67 reads (34%) | catalogued as rs767716338; called by muse, mutect2, varscan2
- ATRNL1 | c.3795+48191del | Intron (DEL) | VAF 10/82 reads (12%) | called by mutect2, pindel
- C3P1 | n.2727T>G | RNA (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- C8orf74 | c.-8C>A | 5'UTR (SNP) | VAF 63/216 reads (29%) | catalogued as COSV58755537; called by muse, mutect2, varscan2
- CACNA2D1 | c.2763+32A>T | Intron (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- CALM1 | c.4-967T>G | Intron (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- CARS1 | c.-30G>T | 5'UTR (SNP) | VAF 23/59 reads (39%) | catalogued as rs745951684; called by muse, mutect2, varscan2
- CD28 | chr2:203706586 C>A | 5'Flank (SNP) | VAF 29/122 reads (24%) | catalogued as COSV100142609; called by muse, mutect2, varscan2
- CLEC10A | c.676-118C>A | Intron (SNP) | VAF 5/13 reads (38%) | catalogued as rs1386795842; called by muse, mutect2, varscan2
- CRISP2 | c.-4A>T | 5'UTR (SNP) | VAF 45/161 reads (28%) | called by muse, mutect2, varscan2
- CYP11B2 | c.*22C>A | 3'UTR (SNP) | VAF 6/32 reads (19%) | called by mutect2, varscan2
- DEPDC1B | c.49-569T>C | Intron (SNP) | VAF 5/35 reads (14%) | called by muse, varscan2
- DUSP22 | c.*6C>A | 3'UTR (SNP) | VAF 38/370 reads (10%) | called by muse, mutect2, varscan2
- EI24P4 | n.901C>A | RNA (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- ELL3 | c.168+56_168+59delinsCCC | Intron (DEL) | VAF 25/146 reads (17%) | called by pindel, varscan2*
- FKBP9P1 | chr7:55691431 G>T | 5'Flank (SNP) | VAF 49/175 reads (28%) | called by muse, mutect2, varscan2
- GPHN | c.729+1351A>G | Intron (SNP) | VAF 68/179 reads (38%) | called by muse, mutect2, varscan2
- GUSBP1 | n.108G>T | RNA (SNP) | VAF 62/222 reads (28%) | catalogued as rs759699158; called by muse, mutect2, varscan2
- GUSBP10 | n.579C>G | RNA (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- HCRTR2 | c.-5C>A | 5'UTR (SNP) | VAF 93/214 reads (43%) | called by muse, mutect2, varscan2
- HMG20B | c.-10C>T | 5'UTR (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- IDNK | c.51-1535G>A | Intron (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- KCNN1 | c.-39del | 5'UTR (DEL) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- KRT74 | c.-51A>G | 5'UTR (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- LUC7L | c.61+45_61+72del | Intron (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel
- MSR1 | c.1034-567G>C | Intron (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- MYO15A | c.9387-44A>T | Intron (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- NOS3 | c.2985-562C>G | Intron (SNP) | VAF 4/25 reads (16%) | called by muse, varscan2
- NPIPB1P | n.690C>A | RNA (SNP) | VAF 119/407 reads (29%) | catalogued as rs557234716; called by muse, mutect2, varscan2
- OSGIN1 | n.1685G>C | RNA (SNP) | VAF 20/117 reads (17%) | catalogued as COSV59420476; called by muse, mutect2, varscan2
- PDGFD | c.125-36765G>T | Intron (SNP) | VAF 40/136 reads (29%) | called by muse, mutect2, varscan2
- PPIP5K1 | c.3500-770A>G | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, varscan2
- PTPRQ | c.19+1200C>A | Intron (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- RFPL4AP1 | n.432C>A | RNA (SNP) | VAF 72/290 reads (25%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159005 G>A | 5'Flank (SNP) | VAF 10/25 reads (40%) | catalogued as rs1267720077; called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159887 C>A | 5'Flank (SNP) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- RNA5-8SP2 | chr16:34159888 G>C | 5'Flank (SNP) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- SEC14L3 | c.54+658T>A | Intron (SNP) | VAF 10/86 reads (12%) | called by mutect2, varscan2
- SELENOS | c.76+156G>A | Intron (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- SHOC2 | c.-235+17380G>A | Intron (SNP) | VAF 37/127 reads (29%) | called by muse, mutect2, varscan2
- SSPOP | n.6606G>A | RNA (SNP) | VAF 16/28 reads (57%) | catalogued as rs1371298232; called by muse, mutect2, varscan2
- SULT1C2 | c.278-2203A>G | Intron (SNP) | VAF 6/50 reads (12%) | catalogued as COSV52266858; called by mutect2, varscan2
- TBC1D22A | c.63-3187T>G | Intron (SNP) | VAF 7/48 reads (15%) | catalogued as rs1339841813; called by muse, mutect2, varscan2
- UMPS | c.156+908G>T | Intron (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- UQCRB | c.*3684G>T | 3'UTR (SNP) | VAF 19/88 reads (22%) | called by muse, mutect2, varscan2
- ZAP70 | c.564-42del | Intron (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- ZNF131 | chr5:43120013 A>G | 5'Flank (SNP) | VAF 7/41 reads (17%) | catalogued as rs1163968436; called by muse, mutect2, varscan2
- ZNF467 | c.*119A>T | 3'UTR (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
